Surgical pathology report (de-identified scan), TCGA case TCGA-SP-A6QG, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Health Network, specimen TCGA-SP-A6QG-01A (Primary Tumor).

LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Copy To: [REDACTED]

Service: [REDACTED]

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Accession #: [REDACTED]

Collected: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Specimen(s) Received

1. Adrenal: Right Resection

Diagnosis

Extra-adrenal paraganglioma, 4.4cm: Soft tissue, para-adrenal

No pathological diagnosis: Adrenal

- (right) adrenalectomy specimen

Comment

The adrenal gland is intact and unremarkable, with no evidence of medullary hyperplasia. The paraganglioma is not connected with or involving the adrenal.

Electronically verified by:

Gross Description

The specimen container labeled with the patient's name and as "adrenal: right resection" contains an adrenalectomy specimen that weighs 78.3 g and measures 10.8 x 7.5 x 3 cm. The adrenal gland with the mass measures 6 x 3 x 0.7 cm. The surrounding yellow adipose tissue ranges from 0.2 to 2.0 cm in thickness, and the thin layer of fascia overlying the adipose tissue measures 9.0 x 3.5 cm in surface area. The external surface is painted with silver nitrate. After the fat is trimmed, the adrenal gland with tumor weighs 45.7 g. On section the mass is a thinly encapsulated, coarsely lobulated nodule that measures 4.4 x 4.0 x 3.0 cm and has a shiny bulging golden-brown cut surface with focal black discoloration. The mass lies 0.3 cm away from the adrenal gland and does not grossly appear to communicate with it. The adrenal gland is grossly unremarkable. The surrounding fat does not contain any grossly identified nodules or lymph nodes. Sections of tumor and normal adrenal are frozen for tumor banking. The remainder of the specimen is submitted as follows:

1A-AB tumor with adrenal gland serially sectioned and submitted in toto.

Dual/Syncronous Primary/Noted		✓

Source: NCI Genomic Data Commons file bdc87142-5b86-460b-8cb9-4b711696cadc (TCGA-SP-A6QG.06BD9582-92E2-4642-A34F-CF4050813A38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).